FM case AD14920 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/57431708-4761-471e-a3c0-776b35adc223

Female, 64.2 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vagina; primary biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
